Somatic mutation profile of tumor specimen HCM-BROD-0008-C25-86A (aliquot HCM-BROD-0008-C25-86A-01D-A78L-36) from HCMI case HCM-BROD-0008-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.5 years (23,186 days).
Specimen HCM-BROD-0008-C25-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c207e1d-e928-4137-b417-06a83ac5fd43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0008-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0008-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c66aaf0b-629d-49b0-a2d2-07329bb3ff8f

The open-access MAF lists 142 somatic variants for this specimen: 98 protein-altering or splice-affecting, 23 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 23, Intron 10, Nonsense Mutation 8, Frame Shift Del 6, RNA 4, Frame Shift Ins 3, 3'UTR 3, 3'Flank 2, Splice Site 2, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 248/347 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 362/363 reads (100%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- ABCA3 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV57054013; called by muse, mutect2, varscan2
- ALDH1L1 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 102/651 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775642396; called by muse, mutect2, varscan2
- ARAP3 | c.2507C>G p.S836* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV53348420; called by muse, mutect2, varscan2
- B3GALT2 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs555499650; called by muse, mutect2, varscan2
- BICC1 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 152/459 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200282277; called by muse, mutect2, varscan2
- DSCAM | c.948del p.T317Pfs*21 | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | catalogued as COSV68027109; called by mutect2, pindel, varscan2
- FLAD1 | c.218dup p.C74Vfs*28 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | catalogued as rs772370005; called by mutect2, pindel, varscan2
- GOLGA6L22 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 206/309 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.225); catalogued as rs1459454497; called by mutect2, varscan2
- KRT81 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 79/551 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs760791254; called by muse, mutect2, varscan2
- KRTAP2-4 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs1161588095, COSV67458617; called by muse, mutect2, varscan2
- LAMC3 | c.2816G>T p.R939L | Missense Mutation (SNP) | VAF 141/406 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs777019483; called by muse, mutect2, varscan2
- LRP1B | c.11954G>A p.W3985* | Nonsense Mutation (SNP) | VAF 110/350 reads (31%) | catalogued as COSV67232700, COSV67256675; called by muse, mutect2, varscan2
- LY75-CD302 | c.5622A>C p.*1874Yext*? | Nonstop Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as rs1346939051, COSV99374197; called by muse, mutect2
- MAGEA3 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 116/747 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV64755972; called by muse, mutect2, varscan2
- NEB | c.13439T>C p.I4480T | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764500250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTSR1 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 151/338 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs754914970; called by muse, mutect2, varscan2
- OR10J1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71129224; called by muse, mutect2, varscan2
- PTPRG | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs764776482, COSV55640529; called by muse, mutect2, varscan2
- RABEP2 | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62869584; called by muse, mutect2, varscan2
- RAE1 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64798027; called by muse, mutect2, varscan2
- SFSWAP | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs1441863628, COSV55523363; called by muse, mutect2, varscan2
- SLC28A1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 167/498 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1037805732, COSV54483325; called by muse, mutect2, varscan2
- SLC9A1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs754510627; called by muse, mutect2, varscan2
- SNAPC4 | c.2731A>G p.T911A | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100047730; called by muse, mutect2, varscan2
- STAB1 | c.3862C>T p.Q1288* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as rs1206217550; called by muse, mutect2, varscan2
- TAS1R3 | c.1957del p.L653Cfs*14 | Frame Shift Del (DEL) | VAF 127/413 reads (31%) | catalogued as COSV104411930; called by mutect2, pindel, varscan2
- ZBED6 | c.1808A>T p.E603V | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV59745634; called by muse, mutect2, varscan2
- A4GALT | c.998T>A p.L333Q | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADAM7 | c.2209-2A>G p.X737_splice | Splice Site (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- AKT1S1 | c.502T>A p.S168T (on ENST00000344175 / NM_001098633.4; = p.S188T on NM_032375.5) | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGEF40 | c.2385G>T p.W795C | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARMCX5 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 140/236 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- B3GALT2 | c.578T>G p.L193* | Nonsense Mutation (SNP) | VAF 54/191 reads (28%) | called by muse, mutect2, varscan2
- BRD1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 258/492 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDK12 | c.1801T>A p.S601T | Missense Mutation (SNP) | VAF 84/406 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CELSR3 | c.3991T>C p.S1331P | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CIB2 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CLSTN3 | c.51_64+7del p.X17_splice | Splice Site (DEL) | VAF 200/364 reads (55%) | called by mutect2, pindel, varscan2
- CNGA2 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 142/361 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN3 | c.850A>C p.I284L | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- DCHS1 | c.6295A>G p.N2099D | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DOCK5 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DOCK7 | c.4227A>C p.E1409D (on ENST00000635253 / NM_001367561.1; = p.E1378D on NM_033407.3) | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DSPP | c.261A>T p.E87D | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- FBXW11 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD3 | c.927C>G p.D309E | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GLRA1 | c.1335C>G p.I445M (on ENST00000455880 / NM_001146040.2; = p.I437M on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- GLRA4 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 130/810 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IGKV1D-33 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by mutect2, varscan2
- IRS4 | c.2375dup p.N792Kfs*33 | Frame Shift Ins (INS) | VAF 215/704 reads (31%) | called by mutect2, pindel, varscan2
- KALRN | c.2882A>G p.Q961R | Missense Mutation (SNP) | VAF 130/523 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIF21B | c.3407A>C p.K1136T | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KLHL4 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- KTN1 | c.3592G>C p.D1198H (on ENST00000395314 / NM_001271014.2; = p.D1169H on NM_004986.4) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- LAMA3 | c.2058T>A p.C686* | Nonsense Mutation (SNP) | VAF 126/3671 reads (3%) | called by muse, mutect2
- LILRA5 | c.700A>T p.I234F | Missense Mutation (SNP) | VAF 119/392 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- LONP2 | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MCF2 | c.2206dup p.C736Lfs*6 | Frame Shift Ins (INS) | VAF 128/761 reads (17%) | called by mutect2, pindel, varscan2
- MCM5 | c.642_644del p.I214del | In Frame Del (DEL) | VAF 82/160 reads (51%) | called by pindel, varscan2
- MEGF10 | c.216C>G p.H72Q | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MRC2 | c.2905C>A p.L969M | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MROH9 | c.77A>T p.H26L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPS5 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MUC19 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MYBBP1A | c.2846A>C p.K949T | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MYLK | c.4242G>T p.E1414D | Missense Mutation (SNP) | VAF 93/392 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NAP1L3 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- NLRP10 | c.1123T>A p.L375I | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NOX3 | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR10G7 | c.662T>G p.V221G | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.794); called by muse, mutect2
- PCYT1A | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPFIBP1 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 116/510 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM14 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- RNF213 | c.3965A>C p.K1322T | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RPAP1 | c.3972+4A>C | Splice Region (SNP) | VAF 62/197 reads (31%) | called by muse, mutect2, varscan2
- SENP5 | c.1313A>G p.N438S | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A3 | c.994T>G p.L332V | Missense Mutation (SNP) | VAF 129/469 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SNURF | c.174A>T p.E58D | Missense Mutation (SNP) | VAF 153/456 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB2 | c.4565G>T p.G1522V | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STT3B | c.1253del p.L418Hfs*39 | Frame Shift Del (DEL) | VAF 114/237 reads (48%) | called by mutect2, pindel, varscan2
- TECR | c.587_588del p.L196Rfs*119 | Frame Shift Del (DEL) | VAF 345/937 reads (37%) | called by mutect2, pindel, varscan2
- TEX13C | c.2452A>T p.K818* | Nonsense Mutation (SNP) | VAF 435/728 reads (60%) | called by muse, mutect2, varscan2
- TG | c.8062T>G p.F2688V | Missense Mutation (SNP) | VAF 111/568 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- THNSL1 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 199/313 reads (64%) | called by muse, mutect2, varscan2
- TMEM132A | c.1153A>C p.M385L (on ENST00000453848 / NM_178031.3; = p.M386L on NM_017870.4) | Missense Mutation (SNP) | VAF 103/307 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TMEM151B | c.1121A>T p.E374V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOPBP1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 280/485 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TRIM56 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 120/190 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRPC5 | c.269del p.L90Rfs*41 | Frame Shift Del (DEL) | VAF 94/522 reads (18%) | called by mutect2, pindel*, varscan2
- TSPAN5 | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UGT3A1 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 93/186 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WHAMM | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF155 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 117/349 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF551 | c.1018_1027del p.C340Pfs*148 | Frame Shift Del (DEL) | VAF 52/279 reads (19%) | called by mutect2, pindel, varscan2
- ZPBP2 | c.503A>C p.K168T (on ENST00000348931 / NM_199321.3; = p.K146T on NM_198844.3) | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.185); called by muse, mutect2
- ZRANB3 | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASTN2 | c.684C>T p.Y228= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs753397797, COSV57754418; called by muse, mutect2
- CD109 | c.1977A>G p.E659= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- CFAP251 | c.3066C>T p.I1022= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as rs187982927; called by muse, mutect2, varscan2
- CNTNAP4 | c.1938T>C p.N646= | Silent (SNP) | VAF 77/105 reads (73%) | catalogued as COSV56670463; called by muse, mutect2, varscan2
- DCBLD2 | c.939G>A p.V313= | Silent (SNP) | VAF 124/640 reads (19%) | called by muse, mutect2, varscan2
- DKK2 | c.448C>A p.R150= | Silent (SNP) | VAF 109/110 reads (99%) | catalogued as rs1254069801, COSV53397188, COSV53400080; called by muse, mutect2, varscan2
- DMWD | c.1035C>T p.G345= | Silent (SNP) | VAF 121/170 reads (71%) | catalogued as rs142998214; called by muse, mutect2, varscan2
- FGFRL1 | c.6G>A p.T2= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as rs1246707687; called by muse, mutect2, varscan2
- FLT4 | c.2553C>T p.L851= | Silent (SNP) | VAF 97/143 reads (68%) | catalogued as rs756742987; called by muse, mutect2, varscan2
- IL16 | c.156C>A p.G52= | Silent (SNP) | VAF 56/166 reads (34%) | called by muse, mutect2, varscan2
- LIFR | c.1569C>T p.S523= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs767207879; called by muse, mutect2, varscan2
- NOL8 | c.1350C>T p.P450= | Silent (SNP) | VAF 96/323 reads (30%) | catalogued as rs1461897210; called by muse, mutect2, varscan2
- OR13G1 | c.720T>G p.S240= | Silent (SNP) | VAF 54/173 reads (31%) | catalogued as COSV62944660, COSV62944925; called by muse, mutect2, varscan2
- OR2H1 | c.570C>A p.T190= | Silent (SNP) | VAF 67/207 reads (32%) | called by muse, mutect2, varscan2
- OSBPL1A | c.2127C>T p.T709= (on ENST00000319481 / NM_080597.4; = p.T196= on NM_018030.4) | Silent (SNP) | VAF 39/1372 reads (3%) | called by muse, mutect2
- PCBP4 | c.894C>T p.I298= (on ENST00000322099 / NM_033010.2; = p.I255= on NM_020418.4) | Silent (SNP) | VAF 96/135 reads (71%) | catalogued as rs199654401; called by muse, mutect2, varscan2
- PCDHA8 | c.1914C>T p.D638= | Silent (SNP) | VAF 128/374 reads (34%) | catalogued as rs782176303, COSV65332432; called by muse, mutect2, varscan2
- PCDHGA2 | c.1965C>T p.S655= | Silent (SNP) | VAF 182/536 reads (34%) | catalogued as rs771072942, COSV99541905; called by muse, mutect2, varscan2
- TAF1A | c.387C>T p.G129= | Silent (SNP) | VAF 46/191 reads (24%) | catalogued as rs1438915794, COSV61919983; called by muse, mutect2, varscan2
- TAF7L | c.138C>T p.S46= | Silent (SNP) | VAF 376/912 reads (41%) | called by muse, mutect2, varscan2
- UGT3A1 | c.1134C>T p.A378= | Silent (SNP) | VAF 94/192 reads (49%) | catalogued as rs762050381; called by muse, mutect2, varscan2
- USP13 | c.969G>T p.S323= | Silent (SNP) | VAF 57/320 reads (18%) | catalogued as COSV99831071, COSV99831916; called by muse, mutect2, varscan2
- ZIM2 | c.837G>A p.P279= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as rs191866455, COSV55639172; called by muse, mutect2, varscan2
- AC064807.1 | n.2759C>T | RNA (SNP) | VAF 62/116 reads (53%) | called by muse, mutect2, varscan2
- APTX | c.134-11A>G | Intron (SNP) | VAF 62/236 reads (26%) | catalogued as rs375978921; called by muse, mutect2, varscan2
- ARSB | c.1213+23258G>A | Intron (SNP) | VAF 111/252 reads (44%) | catalogued as rs995643493; called by muse, mutect2, varscan2
- BMERB1 | c.106+13216C>T | Intron (SNP) | VAF 20/100 reads (20%) | catalogued as rs1445454370; called by mutect2, varscan2
- CABYR | c.*17-287T>G | Intron (SNP) | VAF 116/3936 reads (3%) | called by muse, mutect2
- CALY | c.246+91G>A | Intron (SNP) | VAF 114/180 reads (63%) | called by muse, mutect2, varscan2
- CC2D2B | chr10:96032707 del AAAAGTTTGCACTTTGGATGCTACTGACATG | 3'Flank (DEL) | VAF 36/66 reads (55%) | called by mutect2, pindel
- CCDC107 | chr9:35657772 C>A | 5'Flank (SNP) | VAF 20/90 reads (22%) | catalogued as rs1299479654; called by muse, varscan2
- CPS1 | c.3667-20G>A | Intron (SNP) | VAF 76/267 reads (28%) | catalogued as rs369845787; called by muse, mutect2, varscan2
- DPP10 | c.61-147015C>T | Intron (SNP) | VAF 96/302 reads (32%) | catalogued as rs756659116; called by muse, mutect2, varscan2
- DYNC1H1 | c.*46A>C | 3'UTR (SNP) | VAF 90/290 reads (31%) | called by muse, mutect2, varscan2
- GLRXP3 | n.308G>A | RNA (SNP) | VAF 46/173 reads (27%) | called by muse, mutect2, varscan2
- KRT18P55 | n.1098A>G | RNA (SNP) | VAF 63/293 reads (22%) | called by muse, mutect2, varscan2
- NPC1 | c.3591+47T>C | Intron (SNP) | VAF 82/2484 reads (3%) | called by muse, mutect2
- OR2U1P | n.595T>G | RNA (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- PHACTR1 | c.104-121A>C | Intron (SNP) | VAF 14/84 reads (17%) | catalogued as rs755840858, COSV60662234; called by mutect2, varscan2
- RADIL | c.2291-19C>T | Intron (SNP) | VAF 113/329 reads (34%) | called by muse, mutect2, varscan2
- RPL10 | c.*3G>C | 3'UTR (SNP) | VAF 110/637 reads (17%) | catalogued as COSV99186411; called by muse, mutect2, varscan2
- SYT14 | chr1:210163234 C>G | 3'Flank (SNP) | VAF 103/157 reads (66%) | called by muse, mutect2, varscan2
- UMPS | c.*644dup | 3'UTR (INS) | VAF 45/213 reads (21%) | called by mutect2, pindel, varscan2
- Unknown | chr17:43379201 C>T | IGR (SNP) | VAF 101/253 reads (40%) | called by muse, mutect2, varscan2
